TCGA case TCGA-08-0623 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Brain; Tissue source site: UCSF.
https://portal.gdc.cancer.gov/cases/cdffa77a-ab06-4c2f-9e90-9b349edbaa45

Biospecimens (1 sample)
- Sample TCGA-08-0623-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.4.
